Surgical pathology report (de-identified scan), TCGA case TCGA-E1-5318, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-5318-01A (Primary Tumor).

[page 1 of 2]
Clinical History:

Not provided.

CGA-E1-5318

Gross Examination:

A. "Cortex overlying tumor-brain", fresh and placed in formalin. Received are multiple fragments of tan-brown tissue, measuring 2.0 x 1.5 x 1.0 cm in aggregate. Two fragments corresponding to frozen section AF1 are submitted in Block A1. Five of the larger fragments are submitted in Block A2. The remaining smaller fragments are placed in a mesh bag and submitted in Block A3.

B. "Brain tumor", fresh and placed in formalin. Received are multiple fragments of brain parenchyma, measuring 6.0 x 4.5 x 2.5 cm in aggregate. The tissues are generally tan-brown in color but there are several fragments with red, pink, and dark brown discoloration. The specimen is submitted in its entirety in Blocks B1-B10.

Intraoperative Consultation:

AF1: "Cortex overlying tumor-brain": Glioma, probable oligodendroglioma, grade deferred"

Microscopic Examination:

The specimen submitted as "Brain tumor" consists of large portions of brain which are infiltrated by a neoplastic proliferation of glial cells. The tumor cells exhibit a round regular cytologic shape and are associated with round regular nuclei. Mitotic activity is not readily identified. The vessels in the tumor often are seen to form a mesh-like pattern. Punctate focal calcifications are readily found multifocally. The tumor infiltrates into the overlying cortex and is associated with perineuronal satellitosis. There is no evidence of necrosis within this tumor.

Immunohistochemical Findings:

An immunohistochemical stain for the MibI (proliferation related) antigen reveals the tumor to have a labelling index of 10%.

Continued on next page...

Page: 1

Patient:

MRN:

Location:

[page 2 of 2]
DIAGNOSIS:

A. "CORTEX OVERLYING TUMOR BRAIN":

WELL-DIFFERENTIATED OLIGODENDROGLIOMA-LARGE SIZE.

B. "BRAIN TUMOR":

WELL-DIFFERENTIATED OLIGODENDROGLIOMA-LARGE SIZE. SEE COMMENT.

COMMENT:

The absence of multinucleated giant cells, vascular proliferation, mitotic activity, and necrosis characterize this lesion as a well-differentiated (WHO grade II) neoplasm.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Date Signed: [REDACTED]

** END OF REPORT **

Page: 2

Patient
HX No
Location

Source: NCI Genomic Data Commons file db1c0e75-847c-4ea5-98a6-5ef0ba3c5fae (TCGA-E1-5318.9A5DB4FD-190B-448C-A22A-1B599B9007C5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).